FM case AD11598 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/7c31ec07-9bde-465f-9de4-5baa7daf0ff1

Male, 61.3 years: Adenosquamous carcinoma (ICD-O-3 8560/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
